Surgical pathology report (de-identified scan), TCGA case TCGA-06-0169, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0169-01A (Primary Tumor).

TCGA-06-0169

PATHOLOGICAL DIAGNOSIS:

BRAIN, LEFT PARIETAL, EXCISIONAL BIOPSIES: GLIOBLASTOMA MULTIFORME.

SEE COMMENT.

ADDENDUM DIAGNOSIS:

MIB-1 PROLIFERATION INDEX: 17%.

Operation/Specimen: UPDATED REPORT
Brain.

Clinical History and Pre-Op Dx: [REDACTED] with numbness of right arm, and left parietal enhancing tumor.

GROSS PATHOLOGY: Received fresh, two fragments, 0.9 cm. across in aggregate. Soft, granular, reddish-brown. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, left parietal, smears: High histological grade glioma.

COMMENT: The samples contain portions of glial neoplasm with nuclear atypia, frequent mitotic figures, microvascular cellular proliferation, and areas of necrosis, ie a glioblastoma multiforme.

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, CD34, smooth muscle actin, and MIB-1 were performed on sections from block #1. The GFAP demonstrates fibrillogenesis by the tumor cells. The CD34 and smooth muscle actin depict microvascular cellular proliferation. With the MIB-1 a proliferation index of 17% is determined.

[REDACTED]

Source: NCI Genomic Data Commons file b4660e5e-ec42-4538-a6ce-44e468ff437b (TCGA-06-0169.46DB3ED2-4A31-40A4-B88F-24E2A63A6087.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).